Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9SK, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9SK-01A (Primary Tumor).

[page 1 of 6]
Collected:

Ordered by:

FINAL DIAGNOSIS:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- MODERATE UROTHELIAL ATYPIA WITH INCREASED MITOSES CONSISTENT WITH REACTIVE CHANGE

FINAL DIAGNOSIS:

- SMALL FRAGMENT OF UROTHELIUM SHOWING REACTIVE CELLULAR CHANGES
- NO HIGH-GRADE UROTHELIAL ATYPIA OR CARCINOMA IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO HIGH-GRADE UROTHELIAL ATYPIA OR CARCINOMA IDENTIFIED

FINAL DIAGNOSIS:

- NO HIGH GRADE UROTHELIAL ATYPIA OR CARCINOMA IDENTIFIED

URETHRAL MARGIN (C):

FROZEN SECTION DIAGNOSIS:

- FIBROVASCULAR TISSUE. NO UROTHELIUM IDENTIFIED

FINAL DIAGNOSIS:

- FIBROVASCULAR TISSUE.
- NO UROTHELIAL EPITHELIUM IDENTIFIED

RADICAL CYSTECTOMY (D):

URETHRAL MARGIN (DFS)

FROZEN SECTION DIAGNOSIS:

- NO HIGH-GRADE UROTHELIAL ATYPIA OR CARCINOMA IDENTIFIED

FINAL DIAGNOSIS:

- NO HIGH GRADE UROTHELIAL ATYPIA OR CARCINOMA IDENTIFIED

BLADDER (D):

- HIGH-GRADE TRANSITIONAL CELL CARCINOMA, GRADE 3-4/4, MEASURING 4 X 3 X 2.3 CM, INVOLVING FULL THICKNESS OF THE BLADDER WALL INTO PERIVESICAL SOFT TISSUE
- THE CLOSEST INKED MARGIN IS 1.5 MM AWAY FROM RADIAL INK
- UROTHELIUM ADJACENT TO THE TUMOR SHOWS FOCAL TRANSITIONAL CELL CARCINOMA IN SITU (FLAT LESION)
- PERINEURAL AND VASCULAR INVASION IDENTIFIED
- ALL MARGINS ARE FREE OF TUMOR
- METASTATIC CARCINOMA IDENTIFIED IN ONE OUT OF TWO PERIVESICAL LYMPH NODES (1/2)

PROSTATE (D):

- GRANULOMATOUS PROSTATITIS, BILATERAL LOBES
- NO HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA OR CARCINOMA IDENTIFIED
- BILATERAL SEMINAL VESICLES AND VASA DEFERENTIA, FREE OF TUMOR
- PROSTATIC URETHRA, FREE OF UROTHELIAL DYSPLASIA

PARA-AORTIC LYMPH NODES (E):

- NO TUMOR IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

INNER AORTOCAVAL NODES (F):

- NO TUMOR IDENTIFIED IN ELEVEN LYMPH NODES EXAMINED (0/11)

PARACAVAL NODES (G):

- NO TUMOR IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT COMMON ILIAC LYMPH NODES (H):

- NO TUMOR IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

CLF
Carcinoma, urothelial NOS
path
Carcinoma, transitional cell
Site 4 Bladder NOS
ICD-O 3
8120/3
8120/3
667.9

[page 2 of 6]
Collected:

Ordered by:

Location:

LEFT COMMON ILIAC LYMPH NODES (I):

- NO TUMOR IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

PRESACRAL LYMPH NODES (J):

- NO TUMOR IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

RIGHT EXTERNAL ILIAC LYMPH NODE (K):

- METASTATIC ADENOCARCINOMA IDENTIFIED IN TWO OUT OF TWENTY-FOUR LYMPH NODES EXAMINED (2/24)

RIGHT LYMPH NODE OF CLOQUET (L):

- NO TUMOR IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT OBTURATOR/HYPOGASTRIC LYMPH NODE (M):

- NO TUMOR IDENTIFIED IN THIRTEEN LYMPH NODES EXAMINED (0/13)

LEFT EXTERNAL ILIAC (N):

- NO TUMOR IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

LEFT LYMPH NODE, CLOQUET (O):

- NO TUMOR IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

LEFT HYPOGASTRIC/OBTURATOR (P):

- NO TUMOR IDENTIFIED IN THIRTEEN LYMPH NODES EXAMINED (0/13)

RIGHT PRESACRAL (Q):

- NO TUMOR IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

LEFT PRESACRAL (R):

- NO TUMOR IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT URETERAL STENT (S):

- GROSS EXAMINATION ONLY, AS DESCRIBED

LEFT URETERAL STENT (T):

- GROSS EXAMINATION ONLY, AS DESCRIBED

LEFT COMMON ILIAC #2 (U):

- FIBROCONNECTIVE TISSUE
- NO TUMOR IDENTIFIED

LEFT PROXIMAL URETER (V):

- REACTIVE CELLULAR CHANGES WITH PERIURETERAL TISSUE SHOWING MYXOID DEGENERATION
- NO HIGH-GRADE ATYPIA OR CARCINOMA IDENTIFIED

RIGHT PROXIMAL URETER (W):

- REACTIVE CELLULAR CHANGES WITH PERIURETERAL TISSUE SHOWING MYXOID DEGENERATION
- NO HIGH-GRADE ATYPIA OR CARCINOMA IDENTIFIED

LYMPH NODE SUMMARY: METASTATIC CARCINOMA IDENTIFIED IN THREE OUT OF
A TOTAL OF 108 LYMPH NODES (3/108)

DIAGNOSIS COMMENT:

Sections of the tumor is submitted for p53 analysis and results of which will be issued in an addendum to follow.

INTRAOPERATIVE DIAGNOSIS:

[page 3 of 6]
Collected:

Ordered by:

FROZEN SECTION DIAGNOSIS:

AFS: Right distal ureter:

- moderate urothelial atypia with increased mitoses consistent with reactive change

BFS: Left distal ureter:

- no high-grade urothelial atypia or carcinoma identified

CFS: Urethral margin:

- benign fibrovascular tissue. No urothelium identified

DFS: Urethral margin:

- no high grade urothelial atypia or carcinoma identified

GROSS DESCRIPTION:

A: The specimen is received fresh from the O.R. and labelled "Right distal ureter." It consists of a segment of ureter measuring 0.4 x 0.3 x 0.2 cm. Entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labelled "Left distal ureter." It consists of a segment of ureter measuring 0.4 x 0.3 x 0.2 cm. Entirely submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and "Urethral margin." It consists of a single piece of red-tan soft tissue measuring 2 x 0.2 x 0.2 cm. Entirely submitted for frozen section in cassette CFS.

D: The specimen is received fresh from the O.R. and labelled "Bladder & prostate." It consists of urinary bladder with prostate and bilateral seminal vesicles and vasa deferentia. The specimen measures 32 x 15 x 4 cm overall. The peritoneum measures 26 x 14 cm. The urinary bladder measures 8 x 6 x 3 cm. The right distal ureter measures 7 cm in length and 1 cm in circumference with tan unremarkable mucosa. The left distal ureter measures 6 cm in length and 0.8 cm in circumference with unremarkable mucosa. The prostate measures 4 x 4 x 5.2 cm with unremarkable prostatic urethra (3 cm in length and 4 cm in circumference). The verumontanum measures 1.2 x 0.4 x 0.3 cm. The left seminal vesicle measures 3 x 1 x 0.5 cm, and the right seminal vesicle measures 3 x 1 x 0.5 cm. There is an irregular ulcerative lesion in the trigone area, which measures 4 x 3 x 2.3 cm. This lesion involves the full thickness of bladder wall all the way to the paravesical fatty tissue. The radial ink margin is 2 mm away from the lesion grossly. The bilateral ureteral orifices are involved by the lesion. The lesion is 5.5 cm away from prostatic urethral margin. The urethral margin is submitted for frozen section in cassette DFS. The uninvolved bladder mucosa shows diffuse trabecular pattern with 0.7 cm in thickness. Sectioning of the prostate reveals an unremarkable prostatic parenchyma. Extensive dissection of paravesical fatty soft tissue reveals no distinct lymph node grossly. The peritoneum is uninvolved by the lesion. Representative sections are submitted in 27 cassettes.

E: The specimen is received in formalin and labelled "Para aortic lymph nodes." It consists of multiple irregular fragments of tan soft tissue measuring 4 x 2 x 1 cm in aggregate. Entirely submitted in two cassettes.

F: The specimen is received in formalin and labelled "Inner aorto-caval nodes." It consists of a single irregular piece of fatty tan tissue with lymph node measuring 3.5 x 2 x 1 cm. Entirely submitted in two cassettes.

G: The specimen is received in formalin and labelled "Para caval nodes." It

[page 4 of 6]
Collected:

Ordered by:

Location:

consists of an irregular piece of tan fatty tissue with lymph node measuring 3.2 x 1.7 x 1 cm in aggregate. Entirely submitted in two cassettes.

H: The specimen is received in formalin and labelled "Right common iliac lymph nodes." It consists of multiple irregular pieces of tan fatty tissue with lymph node measuring 5 x 4 x 0.7 cm in aggregate. Entirely submitted in three cassettes.

I: The specimen is received in formalin and labelled "Left common iliac lymph nodes." It consists of two pieces of tan fatty tissue with lymph nodes measuring 2 x 1.2 x 0.4 cm in aggregate. Entirely submitted in a single cassette.

J: The specimen is received in formalin and labelled "Presacral lymph nodes." It consists of multiple irregular pieces of tan fatty tissue with lymph nodes measuring 2 x 1 x 0.8 cm in aggregate. Entirely submitted in a single cassette.

K: The specimen is received in formalin and labelled "Right external iliac LN." It consists of multiple irregular pieces of yellow-tan, fatty tissue with lymph nodes measuring 6 x 4 x 1.2 cm in aggregate. Entirely submitted in five cassettes.

L: The specimen is received in formalin and labelled "Right lymph node of cloquet." It consists of a single irregular piece of yellow-tan fatty tissue with lymph nodes measuring 2 x 1.8 x 0.4 cm. Entirely submitted in a single cassette.

M: The specimen is received in formalin and labelled "Right obturator / hypogastric LN." It consists of multiple irregular pieces of yellow-tan fatty tissue with lymph nodes measuring 5 x 5 x 1.2 cm in aggregate. Entirely submitted in three cassettes.

N: The specimen is received in formalin and labelled "Left external iliac." It consists of multiple irregular pieces of yellow-tan fatty tissue with lymph nodes measuring 3 x 2 x 1 cm in aggregate. Entirely submitted in three cassettes.

O: The specimen is received in formalin and labelled "Left lymph node, cloquet." It consists of a single irregular piece of yellow-tan fatty tissue with lymph nodes measuring 2 x 1 x 0.7 cm. Entirely submitted in a single cassette.

P: The specimen is received in formalin and labelled "Left hypogastric / obturator." It consists of multiple irregular pieces of yellow-tan fatty tissue with lymph nodes measuring 5 x 4 x 1.2 cm in aggregate. Entirely submitted in four cassettes.

Q: The specimen is received in formalin and labelled "Right presciatic." It consists of multiple irregular pieces of tan-yellow fatty tissue with lymph nodes measuring 2 x 1 x 1 cm in aggregate. Entirely submitted in a single cassette.

R: The specimen is received in formalin and labelled "Left presciatic." It consists of multiple pieces of yellow-tan fatty tissue measuring 2 x 1 x 0.4 cm. Entirely submitted in a single cassette.

S: The specimen is received in a plastic bag and labelled "R ureteral stent." It consists of a plastic ureteral stent which measures 45 cm in length and 0.1 cm in diameter. No tissue is identified. Gross examination only.

T: The specimen is received in a plastic bag and labelled "L ureteral stent." It consists of a plastic ureteral stent which measures 45 cm in length and 0.1 cm in diameter. No tissue is identified. Gross examination only.

U: The specimen is received in formalin and labelled "Left common iliac #2." It consists of a single piece of soft tan tissue measuring 1.2 x 1 x 0.4 cm in aggregate. Entirely submitted in a single cassette.

[page 5 of 6]
Temporary Copy

Collected:

Ordered by:

V: The specimen is received in formalin and labelled "Left proximal ureter." It consists of a segment of ureter measuring 1.5 cm in length and 0.6 cm in external diameter. The surrounding soft tissue measuring 2 x 0.4 x 0.4 cm. Entirely submitted in a single cassette.

W: The specimen is received in formalin and labelled "Right proximal ureter." It consists of a segment of ureter measuring 1.2 cm in length and 0.5 cm in external diameter. The specimen is trisected and entirely submitted in a single cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
CFS: frozen section, urethral margin
DFS: frozen section, urethral margin
D1: right distal ureter margin and left ureter orifices with lesion
D2: left distal ureter margin with distal ureter orifice and lesion
D3-5: representative lesion, full thickness
D6,7: representative lesion with benign mucosa
D8,9: representative mucosa from trigone
D10-12: random mucosa of bladder
D13: right distal prostate
D14: left distal prostate
D15: right mid anterior lobe of prostate
D16: right mid posterior lobe of prostate
D17: left mid anterior prostate
D18: left mid posterior prostate
D19: right mid posterior prostate
D20: left mid posterior prostate
D21: right proximal prostate
D22: left proximal prostate
D23: right seminal-vesical junction
D24: left seminal-vesical junction
D25,26: paravesical soft tissue
D27: peritoneum
E1,2: para-aortic lymph nodes
F1,2: inner aortocaval nodes
G1,2: paracaval nodes
H1-3: right common iliac lymph nodes
I: left common iliac lymph nodes
J: presacral lymph nodes
K1-5: right external iliac lymph nodes
L: right lymph node of cloquet
M1-3: right obturator/hypogastric lymph nodes
N1-3: left external iliac
O: left lymph node, cloquet
P1-4: left hypogastric/obturator
Q: right presciatic
R: left presciatic
U: left common iliac #2
V: left proximal ureter
W: right proximal ureter

MICROSCOPIC DESCRIPTION:

A-C: See microscopic-diagnoses.

D: Sections of urinary bladder show high-grade transitional cell carcinoma involving full thickness of bladder wall into perivesical soft tissue. The closest

[page 6 of 6]
Collected

Ordered by

radial margin is 1.5 mm of ink (slice D3). The tumor is characterized by solid sheets of tumor cells infiltrating the bladder wall with areas of necrosis. Perineural invasion and vascular involvement is also identified. Adjacent urothelium show focal in situ carcinoma (flat lesion) and the bilateral ureteral orifices show moderate urothelial dysplasia. Sections of prostate show diffuse granulomatous prostatitis involving both left and right lobes. No high-grade PIN or adenocarcinoma identified. All margins are free of tumor. Metastatic transitional cell carcinoma is identified in one out of two perivesical lymph nodes.

E-W: See microscopic-diagnoses.

Signed by:

ELECTRONIC SIGNATURE

PRE-OPERATIVE DIAGNOSIS:

Transitional cell carcinoma of the bladder

ORDERING PHYSICIAN:

Ordering Physician:

Source: NCI Genomic Data Commons file 21c7c530-e0c7-4c70-b545-0a59c44c7cc2 (TCGA-XF-A9SK.473BCE6C-7925-4E58-9257-B94046C707AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).